TCGA case TCGA-KF-A41W — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ca0f032b-a34c-4a92-a403-bc7dc6eca8e9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (1; GDC holds 2 diagnosis records for this case, 1 of them empty or duplicates of those shown)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 71.1 years (25,969 days); Year of diagnosis: 2012; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Sites of involvement: Uterus; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved.
   Pathology details: Measurement type: Pathologic; Tumor burden: 8.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7; Tumor length measurement: 8.5; Tumor width measurement: 7.8.

Follow-up (2 entries)
- Days to follow up: 181 days; Disease response: Tumor Free.
- Days to follow up: 356 days; Disease response: Tumor Free.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KF-A41W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,050 mg.
  Slide TCGA-KF-A41W-01A-01-TSA: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KF-A41W-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KF-A41W-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-KF-A41W-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 850 mg.
  Slide TCGA-KF-A41W-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic depth: 7.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 61; Days from index date to pharmaceutical treatment ended: 137; Pharmaceutical therapy drug name: Taxotere; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Other malignancy form: Malignancy type: Prior Malignancy.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had an unknown prior tumor of the skin. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 356 days; disease-specific survival: no event (censored), 356 days; progression-free interval: no event (censored), 356 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KF-A41W-01A-11D-A24M-01): tumor purity 0.58, ploidy 2.56, whole-genome doublings 1.
